Surgical pathology report (de-identified scan), TCGA case TCGA-MA-AA41, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-MA-AA41-01A (Primary Tumor).

[page 1 of 3]
Results

SURGICAL PATHOLOGY

Entry Date _____

Component Results

Component

Surgical Pathology

(note)

Outside consultation report

ECDO-3

*Carcinoma, squamous cell NOS
8670/3*

*Date: Cervix NOS
253.9*

JW 4/11/14

Accession #:

Collected:

Received:

Specimen(s) Received:

Cervix, biopsy

Clinical Information

Pertinent History/Operative Findings: Cervix abnormal appears to be cancer.

Specimen Material: Cervix.

Interpretation

This case was reviewed by Dr. _____ at _____
who concurs with the original diagnosis. The entire report
can be viewed in its entirety scanned _____ in
the patient's _____ chart.

****Electronically Signed Out****

Staff Pathologist

Result History

SURGICAL PATHOLOGY (Order _____) on _____ Order Result History Report.

Lab Information

Resulting Lab

Order Information

Order Date _____ Order Time _____

Result Information

Result Date and Time	Status	Priority
	Edited Result -	Routine
	FINAL	

Received Date/Time

Received Date _____ Received Time _____

[page 2 of 3]
Order Providers

Authorizing Provider	Encounter Provider
----------------------	--------------------

Encounter[View Encounter](#)**Reviewed by List**

Order	SURGICAL PATHOLOGY	(Order
--------------	---------------------------	---------------

Administration Details

No Administrations
Recorded

Order Information

Order Date/Time	Release Date/Time	Start Date/Time	End Date/Time
-----------------	-------------------	-----------------	---------------

Order Details

Frequency ONCE	Duration 1 occurrence	Priority Routine	Order Class Normal
-------------------	--------------------------	---------------------	-----------------------

Quantity

Ordering Quantity
1

Original Order

Ordered On	Ordered By
------------	------------

Transfer Service**Collection Information**

Collection Date	Collection Time	Resulting Agency
-----------------	-----------------	------------------

Provider Information

Ordering User	Authorizing Provider
Attending Provider(s)	

Order-Level Documents:

There are no order-level documents.

Encounter[View Encounter](#)**Orders Needing Specimen Collection**

** None **

[page 3 of 3]
Consultation Report

Department of Pathology

Received:
cc

Accession:

Mail to:

Case type: Outside Referral

MATERIALS RECEIVED

Accession #	Collected	Received	Slides	Blocks	UnstSlides
			6	0	0

DIAGNOSIS

Six outside slides

Cervix, biopsy:

INVASIVE SQUAMOUS CARCINOMA, MODERATELY DIFFERENTIATED.

CARCINOMA INVOLVES THE FULL THICKNESS OF THE BIOPSY AND
INVADES AT LEAST 0.8 CM IN DEPTH.

Entire report and diagnosis completed by

BIOMARKER TESTING

Primary Tumor Block: 2

SNOMED CODES

T-83200, M-80703

Note: Representative slide(s) are retained for additional patient care and follow-up purposes. If you would like to have all the slides returned please contact the department with this request at

*Some tests reported here may have been developed and performance characteristics determined by
These tests have not been specifically cleared or approved by the U.S. Food and Drug Administration.*

Entire report and diagnosis completed by:

Page 1 of 1

Consultation Report
File under: Pathology

Source: NCI Genomic Data Commons file a9c88960-5e3f-468f-8ed8-c2602ea6373a (TCGA-MA-AA41.3E26B1B5-771B-4F99-BB78-C83C9F6557D2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).